Surgical pathology report (de-identified scan), TCGA case TCGA-77-8154, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8154-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

#REC.: No collection time was given. Received time has been entered

Histopathology Report

HISTORY

Lung cancer.

MACROSCOPIC

Two specimens received:

1: The specimen is labelled 'right lower lobe' and consists of a right lower lobectomy with inflated measurements of 135 x 130 x 65 mm. There is a line of staples measuring 80 mm. Sectioning reveals a pale firm mass measuring 28 x 25 x 25 mm. The mass is greater than 30 mm from the bronchial resection margin, 30 mm from the hilar resection margin and 5 mm from the overlying diaphragmatic pleura. The mass appears to involve a bronchus. Distal to the tumour, the lung parenchyma is mottled and yellow. Away from the tumour, the lung parenchyma shows diffuse black deposits. [Representative sections: 1A, shave of bronchial resection margin en face; 1B, LS bronchial resection margin; 1C, tumour and pleura; 1D-E, tumour and bronchus; 1F, peribronchial node adjacent to tumour; 1G, mottled lung adjacent to tumour; 1H, peribronchial nodes; 1I, lung distal to tumour; 1J, TS lung away from lesion].

2: The specimen is labelled 'hilar lymph node' and consists of three blackened fatty fragments of tissue measuring in aggregate 20 x 15 x 3 mm. [BIT, 2A].

MICROSCOPY

1: Sections reveal a moderately differentiated squamous cell carcinoma. The lesion partially obliterates a bronchus which shows a focal area in keeping with carcinoma in situ. Tumour does not involve the visceral pleura and is clear of the bronchial resection margin. No lymphatic invasion or perineural permeation by tumour is seen. No definite vascular invasion is identified. Some peribronchial lymph nodes show silicotic nodules characterised by hyalinised fibrous tissue, calcification and scattered flecks of birefringent material. No tumour is identified within peribronchial lymph nodes. Lung parenchyma immediately adjacent to the tumour shows features of obstructive pneumonitis, acute bronchopneumonia and pulmonary oedema. Distant lung parenchyma contains scattered mixed dust macules with focal mild interstitial fibrosis noted. Mild emphysema is also present.

2: Sections of the lymph nodes reveal silicotic nodules, sinus histiocytosis and carbon pigment deposition. No tumour is identified.

SUMMARY

1&2: Right lower lobectomy and separately submitted hilar lymph node:
Moderately differentiated squamous cell carcinoma.
Tumour size 28mm in diameter.
Visceral pleura not involved.
Bronchial resection margin clear.

[page 2 of 2]
Collected

#REC.: No coll

Histopathology Report

No lymphatic, vascular or perineural invasion identified.

Lymph nodes not involved by tumour.

Pathological stage: T1 N0.

Anthracosilicosis, emphysema; pneumonia in lung parenchyma immediately adjacent to tumour.

CC Lung Cancer Registry

Source: NCI Genomic Data Commons file ebc9db4c-cbe1-4db6-92d5-115a038c0474 (TCGA-77-8154.B8CAA915-6710-4E03-B4B2-4641F6A8EACC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).